Somatic mutation profile of tumor specimen TCGA-32-1986-01A (aliquot TCGA-32-1986-01A-01D-1494-08) from TCGA case TCGA-32-1986, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 68.6 years (25,061 days).
Specimen TCGA-32-1986-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10ba1ef7-3c38-4d74-9d96-c0d0599ab16e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-32-1986-10A (Blood Derived Normal), aliquot TCGA-32-1986-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5dadaf79-98f2-45ed-a944-62df84b9ce8f

The open-access MAF lists 43 somatic variants for this specimen: 32 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 28, Silent 11, Splice Region 2, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2531T>C p.L844P | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs137854566, CM040780, CM971041, COSV62210964; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- AGAP3 | c.2188C>T p.R730W (on ENST00000622464; = p.R766W on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776910050, COSV68243216; called by muse, mutect2
- C22orf23 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 73/161 reads (45%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs764924637, COSV50777940; called by muse, mutect2, varscan2
- C8B | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 64/216 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs374321085; called by muse, mutect2, varscan2
- CALD1 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748134346, COSV62650379; called by muse, mutect2, varscan2
- CD3G | c.532C>A p.Q178K | Missense Mutation (SNP) | VAF 69/250 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV52675489; called by muse, mutect2, varscan2
- CDH13 | c.1153G>A p.V385I | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs371866515; called by muse, mutect2, varscan2
- CSF2 | c.24del p.L9Wfs*25 | Frame Shift Del (DEL) | VAF 15/70 reads (21%) | catalogued as COSV51522492; called by mutect2, pindel, varscan2
- FBLN5 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs867912495, COSV50905855; called by muse, varscan2
- FRMD6 | c.833G>T p.G278V (on ENST00000344768 / NM_001267046.2; = p.G270V on NM_152330.4) | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV61089593; called by muse, mutect2, varscan2
- GABRG2 | c.387C>A p.N129K | Missense Mutation (SNP) | VAF 53/227 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as COSV62720019; called by muse, mutect2, varscan2
- GCNA | c.1705C>T p.R569C | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.605); catalogued as rs1243447124, COSV65467567; called by muse, mutect2, varscan2
- GRM3 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 82/436 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64467183, COSV64474717; called by muse, mutect2, varscan2
- HEPACAM2 | c.80-4A>G | Splice Region (SNP) | VAF 56/269 reads (21%) | catalogued as rs368471128; called by muse, varscan2
- HNF4A | c.1159C>T p.H387Y | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV57385990; called by muse, mutect2, varscan2
- ITCH | c.20A>G p.Q7R | Missense Mutation (SNP) | VAF 81/331 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52934285; called by muse, mutect2, varscan2
- KCNB1 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV65568116, COSV65569587; called by muse, mutect2, varscan2
- LRRK1 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs201889926; called by muse, mutect2, varscan2
- MARCO | c.612G>A p.A204= | Splice Region (SNP) | VAF 16/55 reads (29%) | catalogued as rs374483780; called by muse, mutect2, varscan2
- MGAM | c.2501G>A p.R834Q | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778528944, COSV72073567; called by muse, mutect2, varscan2
- MTCL1 | c.3526G>A p.V1176M (on ENST00000306329 / NM_001378206.1; = p.V857M on NM_015210.4) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.125); catalogued as rs752932785, COSV60403325; called by muse, mutect2, varscan2
- MYO15A | c.3316C>T p.R1106W | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs754781505, COSV52760729; called by muse, mutect2, varscan2
- NKG7 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 69/240 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs746182894, COSV52467822; called by muse, mutect2, varscan2
- PCDHB7 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.055); catalogued as rs267600426, COSV50753987; called by muse, mutect2, varscan2
- PCLO | c.2237A>G p.K746R | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV61649336; called by muse, mutect2, varscan2
- PLEKHH1 | c.412A>C p.K138Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61285610; called by muse, mutect2, varscan2
- PPEF2 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54424411; called by muse, mutect2, varscan2
- RNF168 | c.411A>C p.E137D | Missense Mutation (SNP) | VAF 72/262 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV58838699; called by muse, mutect2, varscan2
- SINHCAF | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 43/253 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV61797531; called by muse, mutect2, varscan2
- SLFN11 | c.1376G>C p.C459S | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57699700; called by muse, mutect2, varscan2
- TAOK3 | c.1957G>A p.D653N | Missense Mutation (SNP) | VAF 53/203 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV66826860; called by muse, mutect2, varscan2
- FSTL5 | c.676_678del p.D226del | In Frame Del (DEL) | VAF 35/176 reads (20%) | called by pindel, varscan2
- C2orf80 | c.399G>A p.L133= | Silent (SNP) | VAF 101/440 reads (23%) | catalogued as COSV58017774; called by muse, mutect2, varscan2
- CEP104 | c.1974C>T p.N658= | Silent (SNP) | VAF 76/321 reads (24%) | catalogued as COSV65518282; called by muse, mutect2, varscan2
- FHDC1 | c.2691A>G p.S897= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as COSV52601467; called by muse, mutect2, varscan2
- KRT34 | c.966C>T p.N322= | Silent (SNP) | VAF 41/202 reads (20%) | catalogued as rs145615462; called by muse, mutect2, varscan2
- MAP1A | c.3135T>C p.A1045= | Silent (SNP) | VAF 39/125 reads (31%) | catalogued as COSV55810722; called by muse, mutect2, varscan2
- NANOG | c.273C>T p.V91= | Silent (SNP) | VAF 52/119 reads (44%) | catalogued as COSV57552015; called by muse, mutect2, varscan2
- OBSCN | c.4416G>A p.E1472= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV52798505; called by muse, mutect2, varscan2
- SENP8 | c.150C>T p.H50= | Silent (SNP) | VAF 77/304 reads (25%) | catalogued as rs1391997363, COSV61768146; called by muse, mutect2, varscan2
- SLC25A45 | c.804C>T p.R268= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as rs907214446, COSV53683236; called by muse, mutect2, varscan2
- TDRD10 | c.42G>C p.L14= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as rs757151932, COSV63811403; called by muse, mutect2, varscan2
- TMCO5A | c.495C>T p.L165= | Silent (SNP) | VAF 50/143 reads (35%) | catalogued as COSV60465286; called by muse, mutect2, varscan2
